Somatic mutation profile of tumor specimen MP2PRT-PATCUA-TMP1-A (aliquot MP2PRT-PATCUA-TMP1-A-1-0-D-A81X-36) from MP2PRT case MP2PRT-PATCUA, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.3 years (1,205 days).
Specimen MP2PRT-PATCUA-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b2db9f3b-30a5-405e-9f75-f13e508a0422.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATCUA-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATCUA-NB1-A-1-0-D-A81X-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ceccf681-a350-4622-94a1-faee76cbb15b

The open-access MAF lists 14 somatic variants for this specimen: 9 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 7, Silent 5, Frame Shift Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DDR1 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 21/783 reads (3%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.689); catalogued as rs112944019, COSV61324852; called by muse, mutect2
- HIRIP3 | c.1364G>A p.R455H | Missense Mutation (SNP) | VAF 46/402 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.877); catalogued as rs771077091; called by muse, mutect2, varscan2
- KRT2 | c.1204G>A p.V402M | Missense Mutation (SNP) | VAF 42/301 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.274); catalogued as rs756976713, COSV59010890, COSV59013378; ClinVar: likely benign; called by muse, mutect2, varscan2
- MITF | c.191G>A p.R64H | Missense Mutation (SNP) | VAF 192/496 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1170368454, COSV58891805; called by muse, mutect2, varscan2
- CACNA1I | c.6413_6439del p.P2138_G2146del | In Frame Del (DEL) | VAF 74/410 reads (18%) | called by mutect2, pindel, varscan2
- HP1BP3 | c.696G>C p.Q232H | Missense Mutation (SNP) | VAF 7/182 reads (4%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.694); called by muse, mutect2
- POTEE | c.2253G>T p.E751D | Missense Mutation (SNP) | VAF 28/556 reads (5%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.005); called by muse, mutect2
- TMEM184A | c.753dup p.F252Lfs*172 | Frame Shift Ins (INS) | VAF 56/481 reads (12%) | called by mutect2, pindel, varscan2
- TRGV2 | chr7:38362858 ACTGTGCC>CTGTT | Missense Mutation (DEL) | VAF 51/126 reads (40%) | called by pindel, varscan2*
- ACO1 | c.544T>C p.L182= | Silent (SNP) | VAF 172/382 reads (45%) | catalogued as rs752101251; called by muse, mutect2, varscan2
- BIRC7 | c.517C>T p.L173= | Silent (SNP) | VAF 163/423 reads (39%) | called by muse, mutect2, varscan2
- FCRL1 | c.834C>G p.A278= | Silent (SNP) | VAF 38/287 reads (13%) | called by muse, mutect2, varscan2
- FUT9 | c.297G>A p.L99= | Silent (SNP) | VAF 169/381 reads (44%) | catalogued as rs1289875406, COSV56147393; called by muse, mutect2, varscan2
- KLHDC7A | c.2289C>T p.T763= | Silent (SNP) | VAF 52/321 reads (16%) | catalogued as rs1235374023; called by muse, varscan2
